Somatic mutation profile of tumor specimen TCGA-91-6829-01A (aliquot TCGA-91-6829-01A-21D-1855-08) from TCGA case TCGA-91-6829, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 79.0 years (28,841 days).
Specimen TCGA-91-6829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c287b92-30d0-4c50-a1a3-edc6e3480c19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6829-11A (Solid Tissue Normal), aliquot TCGA-91-6829-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c396d1a-8cc9-4af7-8acc-91138b476f33

The open-access MAF lists 687 somatic variants for this specimen: 526 protein-altering or splice-affecting, 144 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 446, Silent 144, Nonsense Mutation 38, Splice Site 19, Frame Shift Del 15, Intron 5, RNA 5, Splice Region 3, Frame Shift Ins 3, 5'Flank 3, Translation Start Site 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO7A | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs111033283, CM971011, COSV68685913; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA13 | c.8477G>A p.W2826* | Nonsense Mutation (SNP) | VAF 65/167 reads (39%) | catalogued as COSV71295441; called by muse, mutect2, varscan2
- ABCA7 | c.2536G>T p.G846C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415086439, COSV54038147; called by muse, mutect2, varscan2
- ABCB1 | c.1475G>T p.R492L | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV55964888; called by muse, mutect2, varscan2
- ABCB10 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as COSV100748089; called by muse, mutect2, varscan2
- ABCB10 | c.1726-1G>T p.X576_splice | Splice Site (SNP) | VAF 19/98 reads (19%) | catalogued as COSV100748090; called by muse, mutect2, varscan2
- ABCB5 | c.2462C>G p.T821S (on ENST00000404938 / NM_001163941.2; = p.T376S on NM_178559.6) | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV51722216; called by muse, mutect2
- ABCC9 | c.4638G>C p.M1546I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV53968903, COSV53988054, COSV99687607; called by muse, mutect2
- ABI3BP | c.530C>A p.T177N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52552927; called by muse, mutect2, varscan2
- AC004922.1 | c.1206C>A p.C402* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99403133; called by muse, mutect2, varscan2
- AC100868.1 | c.1886G>T p.G629V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.494); catalogued as COSV51849798, COSV99227109; called by muse, mutect2, varscan2
- ACAN | c.7075G>A p.E2359K (on ENST00000560601 / NM_001369268.1; = p.E2283K on NM_001135.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61370483; called by muse, mutect2, varscan2
- ACP3 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60488889; called by muse, mutect2, varscan2
- ACTN2 | c.1211A>T p.E404V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100856805, COSV63978596; called by muse, varscan2
- ACTN2 | c.1226A>G p.K409R | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs863225115, COSV63978601; ClinVar: uncertain significance; called by muse, varscan2
- ACTN2 | c.1639A>G p.S547G | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1265446111, COSV63978607; called by muse, mutect2, varscan2
- ADAMTS18 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51419211, COSV51423818; called by muse, mutect2, varscan2
- ADGRA3 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 179/538 reads (33%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as COSV51569035; called by muse, mutect2, varscan2
- ADGRD1 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV55438950, COSV55459066; called by muse, mutect2, varscan2
- ADGRE2 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV59696713; called by muse, mutect2, varscan2
- ADGRL4 | c.346C>A p.H116N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV66066553; called by muse, mutect2, varscan2
- AGMO | c.677G>C p.G226A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61119512, COSV61125189; called by muse, mutect2, varscan2
- AHNAK | c.13268G>T p.G4423V | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57232991, COSV99948111; called by muse, mutect2, varscan2
- AHNAK2 | c.16088A>G p.D5363G | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV60932535; called by muse, mutect2, varscan2
- AHNAK2 | c.2867A>T p.D956V | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60932551; called by muse, mutect2, varscan2
- AHSP | c.136A>G p.N46D | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs766420633, COSV56529598; called by muse, mutect2, varscan2
- AK8 | c.930G>T p.R310S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as COSV53761311; called by muse, mutect2, varscan2
- AK8 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100050602; called by muse, mutect2, varscan2
- AK8 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100050606; called by muse, mutect2, varscan2
- AKAP9 | c.5903G>T p.R1968M (on ENST00000359028; = p.R1936M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62359032; called by muse, mutect2, varscan2
- AKR1B10 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV62056725; called by muse, mutect2, varscan2
- ALDH3B2 | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV62429607; called by muse, mutect2, varscan2
- ALMS1 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV52523278; called by muse, mutect2, varscan2
- ALMS1 | c.5600A>G p.D1867G | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs762497192, COSV52523285; called by muse, mutect2, varscan2
- AMER3 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV58470765; called by muse, mutect2, varscan2
- ANK1 | c.2003G>T p.G668V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55897529; called by muse, mutect2
- ANKRD34B | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58614618; called by muse, mutect2, varscan2
- ANKRD7 | c.538A>T p.K180* | Nonsense Mutation (SNP) | VAF 48/148 reads (32%) | catalogued as COSV54556686; called by muse, mutect2, varscan2
- ANO5 | c.1171G>C p.G391R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61090773; called by muse, mutect2, varscan2
- APPBP2 | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV50030176; called by muse, mutect2, varscan2
- AQP4 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs756380305, COSV67219589; called by muse, mutect2, varscan2
- ARFGAP2 | c.42T>G p.F14L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV54068099; called by muse, mutect2, varscan2
- ARHGAP15 | c.79A>T p.R27* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV54517597, COSV54524296; called by muse, mutect2, varscan2
- ARHGAP5 | c.2163G>T p.L721F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100565731; called by muse, mutect2, varscan2
- ARHGAP5 | c.2164G>T p.A722S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100565732; called by muse, mutect2, varscan2
- ARHGEF35 | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | PolyPhen possibly damaging (0.765); catalogued as COSV65313056; called by muse, mutect2
- ASTN2 | c.544C>A p.Q182K | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.071); catalogued as COSV57821162; called by muse, mutect2, varscan2
- ATP13A5 | c.1078G>T p.G360W | Missense Mutation (SNP) | VAF 69/103 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV60876202; called by muse, mutect2, varscan2
- ATP1A4 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs760916457, COSV63625455; called by muse, mutect2, varscan2
- ATR | c.5096A>C p.E1699A | Missense Mutation (SNP) | VAF 119/240 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as COSV63393341; called by muse, mutect2, varscan2
- AVPR2 | c.845T>G p.L282R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as CM001635, COSV61687067; called by muse, mutect2, varscan2
- B3GAT1 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs1298498591, COSV57001084; called by muse, mutect2, varscan2
- B4GALNT4 | c.1222A>T p.M408L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV57326959; called by muse, mutect2, varscan2
- BAIAP2 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs764303213, COSV58373796; called by muse, mutect2, varscan2
- BICC1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778650709, COSV65865298; called by muse, mutect2, varscan2
- BICRA | c.4589G>A p.G1530D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV101194500; called by muse, mutect2, varscan2
- BIRC6 | c.2133del p.K712Sfs*9 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | catalogued as COSV70195901; called by mutect2, pindel, varscan2
- BMP10 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV54897439; called by muse, mutect2, varscan2
- BPHL | c.616T>C p.C206R | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100984588; called by muse, mutect2, varscan2
- BPHL | c.617G>T p.C206F | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100984590; called by muse, mutect2, varscan2
- BPIFB4 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.792); catalogued as COSV64952547; called by muse, mutect2, varscan2
- BRINP3 | c.2261C>A p.P754Q | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1246896771, COSV66542840; called by muse, mutect2, varscan2
- BSG | c.823T>G p.F275V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV100345079; called by muse, mutect2, varscan2
- BTAF1 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV56440071; called by muse, mutect2, varscan2
- BTAF1 | c.4873G>T p.D1625Y | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56440083, COSV56440462; called by muse, varscan2
- C12orf42 | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.951); catalogued as COSV59391544; called by muse, mutect2
- C12orf71 | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV70282917; called by muse, mutect2, varscan2
- C6orf118 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376435891; called by muse, mutect2, varscan2
- C9 | c.424T>C p.C142R | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54682084; called by muse, mutect2
- CACNA1E | c.5180A>T p.E1727V | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62432268; called by muse, mutect2, varscan2
- CACNB1 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59999385, COSV60000546; called by muse, mutect2
- CAND2 | c.1111C>A p.P371T (on ENST00000456430 / NM_001162499.2; = p.P278T on NM_012298.3) | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV99929927; called by muse, mutect2, varscan2
- CAND2 | c.1112C>A p.P371H (on ENST00000456430 / NM_001162499.2; = p.P278H on NM_012298.3) | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.396); catalogued as COSV99929933; called by muse, mutect2, varscan2
- CCDC73 | c.689C>A p.T230K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV58805564; called by muse, mutect2, varscan2
- CCDC83 | c.941G>A p.S314N (on ENST00000342404 / NM_001286159.2; = p.S345N on NM_173556.5) | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.624); catalogued as rs771327040, COSV54705274; called by muse, mutect2, varscan2
- CCDC89 | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1308465609, COSV57034999; called by muse, mutect2, varscan2
- CCKBR | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV58099046, COSV58106205; called by muse, mutect2, varscan2
- CD248 | c.97A>T p.S33C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV60938025; called by muse, mutect2, varscan2
- CD99L2 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV60938768; called by muse, mutect2, varscan2
- CDCA7 | c.376A>C p.K126Q (on ENST00000347703 / NM_145810.3; = p.K205Q on NM_031942.5) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.29); catalogued as COSV60721959; called by muse, mutect2, varscan2
- CDH15 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs776191977, COSV57028149, COSV99228708; called by muse, mutect2, varscan2
- CDH6 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54065495, COSV54079287; called by muse, mutect2, varscan2
- CELA3A | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51587375; called by muse, mutect2, varscan2
- CELF4 | c.631G>C p.A211P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV58455209, COSV58467591; called by muse, varscan2
- CELF4 | c.577+1G>T p.X193_splice | Splice Site (SNP) | VAF 5/72 reads (7%) | catalogued as COSV58467600; called by muse, mutect2
- CENPP | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV52762135; called by muse, mutect2, varscan2
- CEP152 | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57865470; called by muse, mutect2, varscan2
- CLASP2 | c.2081G>T p.R694L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV56295209; called by muse, mutect2, varscan2
- CLCN4 | c.1711A>G p.I571V | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV66468893; called by muse, mutect2, varscan2
- CLEC1B | c.228A>T p.L76F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs200687802, COSV53726748; called by muse, mutect2, varscan2
- CMYA5 | c.6701C>G p.A2234G | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV71408663, COSV71409957; called by muse, mutect2, varscan2
- CNGA3 | c.567G>T p.R189S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV55628664; called by muse, mutect2, varscan2
- CNKSR2 | c.1785G>T p.W595C | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54267698, COSV54268492; called by muse, mutect2, varscan2
- CNR1 | c.29A>G p.D10G | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV62992088; called by muse, mutect2, varscan2
- CNTNAP2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV62168210, COSV62265810; called by muse, mutect2
- CNTNAP3 | c.3253C>T p.H1085Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV52676688; called by muse, mutect2, varscan2
- COASY | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as COSV99888856; called by muse, mutect2, varscan2
- COL19A1 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV59568972; called by muse, mutect2, varscan2
- COL24A1 | c.4783-1G>T p.X1595_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV65315114; called by muse, mutect2
- COL4A6 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV57879957; called by muse, mutect2, varscan2
- CP | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52834522; called by muse, mutect2, varscan2
- CPS1 | c.4474A>G p.R1492G | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV51826167; called by muse, mutect2, varscan2
- CPSF1 | c.3811G>C p.V1271L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV58235655, COSV58235798; called by muse, mutect2, varscan2
- CPXM1 | c.1365C>A p.H455Q | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV66046904; called by muse, mutect2, varscan2
- CSMD1 | c.5512G>A p.G1838S (on ENST00000520002; = p.G1837S on NM_033225.6) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59391352; called by muse, mutect2, varscan2
- CSPP1 | c.1229C>G p.A410G (on ENST00000676605; = p.A369G on NM_024790.6) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV51593374; called by muse, mutect2, varscan2
- CTNNA2 | c.631G>T p.G211W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63562272, COSV63605623; called by muse, mutect2, varscan2
- CTPS1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65454312; called by muse, mutect2
- CX3CR1 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64195553; called by muse, varscan2
- CYP2C19 | c.1150-1G>T p.X384_splice | Splice Site (SNP) | VAF 26/136 reads (19%) | catalogued as COSV64909675; called by muse, mutect2, varscan2
- CYP4V2 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV66507655; called by muse, mutect2, varscan2
- CYTIP | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV51636450; called by muse, mutect2
- DAB1 | c.1354C>A p.Q452K (on ENST00000371231; = p.Q419K on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV64692682, COSV64696908; called by muse, mutect2, varscan2
- DAB1 | c.694T>C p.Y232H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.929); catalogued as COSV59738461; called by muse, mutect2, varscan2
- DACH1 | c.1516A>T p.S506C (on ENST00000619232 / NM_001366712.1; = p.S454C on NM_080759.6) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV57521303; called by muse, mutect2, varscan2
- DCAF8L1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 53/98 reads (54%) | catalogued as COSV71595559; called by muse, mutect2, varscan2
- DCLK3 | c.867G>T p.R289S | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV69364919; called by muse, mutect2, varscan2
- DDX27 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs759277865, COSV65630858; called by muse, mutect2, varscan2
- DGKB | c.2009G>T p.G670V | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51823073, COSV99343744; called by muse, mutect2
- DIAPH2 | c.1506G>C p.K502N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV61294548; called by muse, mutect2, varscan2
- DLGAP4 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.353); catalogued as rs376864546; called by muse, varscan2
- DLGAP4 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.9); catalogued as COSV59424125; called by muse, varscan2
- DLX1 | c.574G>C p.A192P | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV59395456; called by muse, mutect2, varscan2
- DMD | c.1376A>T p.E459V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as CD103867, COSV55868921, COSV55904712; called by muse, mutect2, varscan2
- DNAH8 | c.3019T>A p.F1007I | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV59483969; called by muse, mutect2, varscan2
- DNAH8 | c.11638T>A p.Y3880N | Missense Mutation (SNP) | VAF 130/239 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59483991; called by muse, mutect2, varscan2
- DNAH9 | c.1136C>A p.P379Q | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV52379360; called by muse, mutect2, varscan2
- DNAH9 | c.10294G>A p.D3432N | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV52379369; called by muse, mutect2, varscan2
- DNMBP | c.2992A>G p.I998V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60634006; called by muse, mutect2, varscan2
- DOCK5 | c.126G>A p.E42= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99378169; called by muse, mutect2
- DOCK5 | c.2792G>T p.R931L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV52412606; called by mutect2, varscan2
- DOCK7 | c.121_122insT p.G41Vfs*41 | Frame Shift Ins (INS) | VAF 25/168 reads (15%) | catalogued as COSV99226211; called by mutect2, pindel, varscan2
- DPEP1 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV55362083; called by muse, mutect2, varscan2
- DSG3 | c.1970C>A p.P657Q | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57130077; called by muse, mutect2, varscan2
- DUSP7 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs1291715944, COSV56589862; called by muse, mutect2, varscan2
- DYNC1H1 | c.5677A>T p.T1893S | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV64143515; called by muse, mutect2, varscan2
- DZIP1 | c.2322C>G p.I774M (on ENST00000347108; = p.I755M on NM_014934.5) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs1480915310, COSV61270707; called by muse, mutect2, varscan2
- EAPP | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV51653396; called by muse, mutect2, varscan2
- EBF3 | c.800C>T p.A267V (on ENST00000355311 / NM_001375392.1; = p.A258V on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV62482512; called by muse, mutect2, varscan2
- ECT2L | c.241T>A p.L81I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV62887496; called by muse, mutect2, varscan2
- EGF | c.3225C>G p.S1075R | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.168); catalogued as COSV54485458, COSV99491450; called by muse, mutect2, varscan2
- ENTHD1 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57325687; called by muse, mutect2, varscan2
- EPB41L4A | c.1377-2A>G p.X459_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as COSV54881981; called by muse, mutect2, varscan2
- EPHA3 | c.1422C>A p.Y474* | Nonsense Mutation (SNP) | VAF 41/101 reads (41%) | catalogued as COSV60729841; called by muse, mutect2, varscan2
- ERGIC3 | c.394T>C p.F132L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54141145; called by muse, mutect2, varscan2
- F2R | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100058711; called by muse, mutect2, varscan2
- FAM153B | c.661G>T p.E221* (on ENST00000253490; = p.E144* on NM_001265615.1) | Nonsense Mutation (SNP) | VAF 56/186 reads (30%) | catalogued as COSV53685372, COSV53688864; called by muse, varscan2
- FAM166A | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV61119153; called by muse, mutect2, varscan2
- FAM78B | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.351); catalogued as COSV57982924; called by muse, varscan2
- FBXO16 | c.821G>T p.R274M | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV60777998; called by muse, mutect2, varscan2
- FBXO31 | c.562T>C p.F188L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100291638; called by muse, mutect2
- FBXO4 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55854423; called by muse, mutect2, varscan2
- FCGR1A | c.647T>G p.L216W | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV64986168; called by muse, varscan2
- FGFR4 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as COSV52810635; called by muse, mutect2, varscan2
- FLG | c.6564T>A p.S2188R | Missense Mutation (SNP) | VAF 117/762 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs1484593961, COSV100910977, COSV64250912; called by muse, mutect2, varscan2
- FLG2 | c.6949C>A p.Q2317K | Missense Mutation (SNP) | VAF 64/421 reads (15%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.678); catalogued as COSV66167608, COSV66170097; called by muse, mutect2, varscan2
- FLT3 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1279372452, COSV54042160, COSV54071413; called by muse, mutect2, varscan2
- FREM1 | c.4553C>A p.A1518D | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV66531027; called by muse, mutect2, varscan2
- FREM2 | c.7839G>C p.Q2613H | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54854376; called by muse, mutect2, varscan2
- FSCB | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV61219716; called by muse, varscan2
- FSCN1 | c.320C>A p.A107E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.093); catalogued as rs758856457, COSV61018929; called by muse, mutect2, varscan2
- FSHR | c.1193G>T p.R398M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58626179; called by muse, mutect2, varscan2
- FSHR | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100436336, COSV100438240; called by muse, mutect2, varscan2
- FTSJ1 | c.401A>C p.Q134P | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50026475; called by muse, mutect2, varscan2
- GABRB1 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55001466; called by muse, mutect2, varscan2
- GAD2 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52169605; called by muse, mutect2, varscan2
- GAD2 | c.1354G>C p.V452L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV52169633; called by muse, mutect2, varscan2
- GAL3ST4 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57588422; called by muse, mutect2
- GBA3 | c.771_772insT p.I258Yfs*6 | Frame Shift Ins (INS) | VAF 17/104 reads (16%) | catalogued as COSV101545582; called by mutect2, pindel, varscan2
- GIPR | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as COSV54426675; called by muse, mutect2, varscan2
- GJA8 | c.949C>G p.Q317E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV53790742, COSV99569770; called by muse, mutect2
- GLRA4 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1259262661, COSV60327895, COSV60328451; called by muse, mutect2, varscan2
- GLT8D2 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV62563296; called by muse, mutect2, varscan2
- GLYAT | c.287T>A p.I96N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53540866; called by muse, mutect2, varscan2
- GNG12 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 24/237 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV100921434; called by muse, mutect2, varscan2
- GOLIM4 | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 88/256 reads (34%) | catalogued as COSV58332296; called by muse, mutect2, varscan2
- GPM6A | c.138C>A p.C46* | Nonsense Mutation (SNP) | VAF 38/103 reads (37%) | catalogued as COSV54535949; called by muse, mutect2, varscan2
- GPR176 | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761921765, COSV54444486; called by muse, mutect2, varscan2
- GPR26 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV52937280; called by muse, mutect2, varscan2
- GPR50 | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | catalogued as COSV54439645; called by muse, mutect2, varscan2
- GPR50 | c.1214A>T p.K405M | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV54443347; called by muse, mutect2, varscan2
- GRIK1 | c.1517C>A p.A506D | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100516089, COSV58733875; called by muse, mutect2, varscan2
- GRIK3 | c.241T>A p.Y81N | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV66147756; called by muse, mutect2, varscan2
- GRIN3A | c.3133G>A p.D1045N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1402121474, COSV62458963; called by muse, mutect2
- H1-6 | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100619670; called by muse, mutect2, varscan2
- H4C12 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100694824, COSV100694826; called by muse, mutect2, varscan2
- H4C5 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100747969, COSV63486720; called by muse, mutect2, varscan2
- HASPIN | c.2140G>C p.D714H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV99561643; called by muse, mutect2, varscan2
- HGF | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs73381183, COSV55957905; called by muse, mutect2, varscan2
- HHIPL2 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58568278; called by muse, mutect2, varscan2
- HIF3A | c.218-1G>A p.X73_splice (on ENST00000377670 / NM_152795.4; = p.X71_splice on NM_152794.4) | Splice Site (SNP) | VAF 36/91 reads (40%) | catalogued as COSV52205304; called by muse, mutect2, varscan2
- HJV | c.999T>A p.N333K (on ENST00000336751 / NM_213653.4; = p.N220K on NM_145277.5) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV60953340; called by muse, mutect2, varscan2
- HK1 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV53866883; called by muse, mutect2
- HNRNPF | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV61562356; called by muse, mutect2, varscan2
- HOXA9 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV58656792; called by muse, mutect2, varscan2
- HOXD12 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV66833014; called by muse, mutect2, varscan2
- INSIG2 | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55523925; called by muse, mutect2, varscan2
- INSR | c.883A>T p.N295Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV100253721; called by muse, mutect2, varscan2
- INTS1 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67176818, COSV67180041; called by muse, mutect2, varscan2
- IPO7 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV63352930; called by muse, mutect2, varscan2
- IQSEC1 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.06); catalogued as COSV56230134, COSV99832391; called by muse, mutect2, varscan2
- IRX2 | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57413996; called by muse, mutect2, varscan2
- ITGA5 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV53220989; called by muse, mutect2, varscan2
- ITIH5 | c.299+1G>A p.X100_splice | Splice Site (SNP) | VAF 14/142 reads (10%) | catalogued as COSV99906015; called by muse, mutect2
- IVL | c.1337A>T p.Q446L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64217364; called by muse, mutect2, varscan2
- JAK1 | c.3421A>T p.S1141C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV53811388; called by muse, mutect2, varscan2
- JMY | c.2917G>C p.E973Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV68662671; called by muse, mutect2, varscan2
- KANSL1L | c.1324G>T p.G442W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV55997723; called by muse, mutect2, varscan2
- KASH5 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV71358561; called by muse, mutect2, varscan2
- KCNA4 | c.1703A>T p.H568L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV60256305; called by muse, mutect2, varscan2
- KCNN4 | c.897C>A p.H299Q | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV53457409; called by muse, mutect2, varscan2
- KCTD3 | c.1974G>C p.R658S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); catalogued as COSV52071267; called by muse, mutect2, varscan2
- KIAA0100 | c.1716G>T p.W572C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101197439; called by muse, mutect2, varscan2
- KIAA0100 | c.1715G>T p.W572L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.373); catalogued as COSV66496816; called by muse, mutect2, varscan2
- KIF11 | c.1259T>A p.V420E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.076); catalogued as COSV53274474; called by muse, mutect2, varscan2
- KIF19 | c.2434C>A p.L812M | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV63430724; called by muse, mutect2, varscan2
- KLHL20 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52945426; called by muse, mutect2, varscan2
- KLHL38 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV58089407; called by muse, mutect2, varscan2
- KMT2C | c.7316A>G p.Y2439C | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51508863; called by muse, mutect2, varscan2
- KPRP | c.846C>A p.Y282* | Nonsense Mutation (SNP) | VAF 46/121 reads (38%) | catalogued as COSV100908829, COSV64223177; called by muse, mutect2, varscan2
- KPRP | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); catalogued as COSV100908830; called by muse, mutect2, varscan2
- KRT19 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.788); catalogued as COSV64239469; called by muse, mutect2
- KRT26 | c.1160A>T p.Y387F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59416033; called by muse, mutect2, varscan2
- KRT28 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV60686645; called by muse, mutect2, varscan2
- KRT73 | c.1303C>G p.R435G | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59841875; called by muse, mutect2, varscan2
- KRTAP5-6 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 50/241 reads (21%) | PolyPhen benign (0.061); catalogued as COSV66289410; called by muse, mutect2, varscan2
- L3MBTL1 | c.550G>C p.E184Q (on ENST00000418998 / NM_001377303.1; = p.E94Q on NM_015478.7) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.343); catalogued as COSV64235398; called by mutect2, varscan2
- LANCL3 | c.896-1G>T p.X299_splice | Splice Site (SNP) | VAF 18/34 reads (53%) | catalogued as COSV101065785; called by muse, varscan2
- LANCL3 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101065535, COSV101065786; called by muse, mutect2, varscan2
- LATS1 | c.2408G>C p.S803T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV53587782, COSV53600928; called by muse, mutect2, varscan2
- LCE3B | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV100167544; called by muse, mutect2, varscan2
- LDB2 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58766599, COSV58784337; called by muse, mutect2, varscan2
- LDHC | c.54C>G p.N18K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV55006240; called by muse, mutect2, varscan2
- LGI3 | c.1379A>T p.Q460L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60444449; called by muse, mutect2, varscan2
- LGR5 | c.761G>T p.R254M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57010602; called by muse, mutect2, varscan2
- LGR6 | c.431G>T p.R144L (on ENST00000367278 / NM_001017403.1; = p.R92L on NM_021636.3) | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55167308, COSV99708122; called by muse, mutect2, varscan2
- LHFPL5 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1458872576, COSV100798919, COSV100799039; called by muse, mutect2, varscan2
- LILRB5 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 46/81 reads (57%) | catalogued as COSV60261470; called by muse, mutect2, varscan2
- LPIN2 | c.2110C>T p.L704F | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55240220; called by muse, mutect2, varscan2
- LRIT1 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV64513676; called by muse, mutect2, varscan2
- LRP12 | c.2182A>G p.S728G | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV52628328; called by muse, mutect2
- LRRC32 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52636014; called by muse, mutect2, varscan2
- LYSMD4 | c.394G>A p.E132K (on ENST00000409796 / NM_001284417.2; = p.E133K on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60386126, COSV60387816; called by muse, mutect2, varscan2
- LYST | c.2894C>G p.S965C | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as rs772671228, COSV67714961; called by muse, mutect2, varscan2
- LZTS1 | c.1088T>A p.L363H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV56118741; called by muse, mutect2, varscan2
- MAD1L1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV56249271; called by muse, mutect2
- MAGEA12 | c.127T>G p.S43A | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV63295552; called by muse, mutect2, varscan2
- MAGEC2 | c.1088G>T p.S363I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.336); catalogued as COSV56001752; called by muse, mutect2, varscan2
- MAGI1 | c.2626G>C p.V876L (on ENST00000402939 / NM_001033057.2; = p.V904L on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58341172; called by muse, mutect2, varscan2
- MAN2A1 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54847260, COSV99811657; called by muse, mutect2, varscan2
- MAN2B2 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV53454027, COSV53457259; called by muse, mutect2, varscan2
- MAP3K7 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65226253; called by muse, mutect2, varscan2
- MARCO | c.943G>C p.V315L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV59059289; called by muse, mutect2, varscan2
- MARK1 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV65071871; called by muse, mutect2
- MCCC1 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55612232; called by muse, mutect2, varscan2
- MECOM | c.1982G>T p.R661M (on ENST00000468789 / NM_001105078.4; = p.R849M on NM_004991.4) | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV52976383; called by muse, mutect2
- MECOM | c.1980G>T p.L660F (on ENST00000468789 / NM_001105078.4; = p.L848F on NM_004991.4) | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV52959934, COSV52976403; called by muse, mutect2
- METAP1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as COSV56443197, COSV56446241; called by muse, varscan2
- MGA | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV54964175; called by muse, mutect2, varscan2
- MICALL2 | c.2620G>T p.D874Y | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV52519220; called by muse, mutect2, varscan2
- MKI67 | c.5905G>A p.E1969K | Missense Mutation (SNP) | VAF 81/352 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64077134; called by muse, mutect2, varscan2
- MRAP | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV100353360; called by muse, mutect2, varscan2
- MS4A3 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99615051; called by muse, mutect2, varscan2
- MS4A3 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.367); catalogued as COSV99615058; called by muse, mutect2, varscan2
- MSC | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV57697650; called by muse, mutect2, varscan2
- MTCL1 | c.1814A>T p.Q605L (on ENST00000306329 / NM_001378206.1; = p.Q245L on NM_015210.4) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV60412581; called by muse, mutect2, varscan2
- MTMR7 | c.754G>C p.A252P | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51668412, COSV51670936; called by muse, mutect2, varscan2
- MUC16 | c.24913G>T p.V8305L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); catalogued as COSV67497732; called by muse, mutect2, varscan2
- MYCT1 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1369702765, COSV65892101; called by muse, mutect2, varscan2
- MYH1 | c.480C>A p.D160E | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV56858136; called by muse, mutect2, varscan2
- MYH15 | c.1559G>T p.W520L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56321059; called by muse, mutect2, varscan2
- MYH2 | c.5104G>C p.E1702Q | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV55430769, COSV55449914; called by muse, mutect2, varscan2
- MYH7 | c.5090G>C p.R1697P | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100805974, COSV62515973, COSV62524616; called by muse, mutect2, varscan2
- MYH7 | c.2466G>T p.M822I | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV62521393, COSV62524621; called by muse, mutect2, varscan2
- MYL7 | c.131T>A p.I44N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56269282; called by muse, mutect2, varscan2
- MYO5B | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs1338751420, COSV53232754; called by muse, mutect2, varscan2
- MYOCD | c.2657C>T p.P886L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58505054; called by muse, mutect2, varscan2
- MYOM2 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.138); catalogued as COSV50786777; called by muse, mutect2, varscan2
- MYOM2 | c.2917G>A p.D973N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); catalogued as COSV50786934; called by muse, mutect2, varscan2
- MYT1 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.401); catalogued as COSV60514838; called by muse, mutect2, varscan2
- NAP1L3 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59077921; called by muse, mutect2, varscan2
- NCAPD2 | c.4151C>T p.T1384I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs747329947, COSV57522226; called by muse, mutect2, varscan2
- NCAPH | c.282C>G p.D94E | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV53639343, COSV99545377; called by muse, mutect2
- NCOA3 | c.3335G>T p.G1112V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV59074010; called by muse, mutect2, varscan2
- NCOR1 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs868025847, COSV51987172, COSV51998879; called by muse, mutect2, varscan2
- NDST2 | c.1910G>T p.S637I | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV55218453; called by muse, varscan2
- NEB | c.11341C>A p.Q3781K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.087); catalogued as COSV99428613; called by muse, mutect2, varscan2
- NEB | c.10771G>T p.V3591L | Missense Mutation (SNP) | VAF 110/234 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV51464300; called by muse, mutect2, varscan2
- NEFL | c.793T>A p.Y265N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55338592; called by muse, mutect2, varscan2
- NF1 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV62206345, COSV62223473; called by muse, mutect2, varscan2
- NGEF | c.1842C>A p.C614* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV50961857; called by muse, mutect2, varscan2
- NIBAN1 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV62288147; called by muse, mutect2, varscan2
- NIBAN3 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373733258; called by muse, mutect2, varscan2
- NIPAL1 | c.866C>A p.T289K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55007844; called by muse, mutect2, varscan2
- NIPAL3 | c.863-2A>G p.X288_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as rs1189553900, COSV50238413; called by muse, mutect2, varscan2
- NIPAL4 | c.536T>A p.V179D | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV61731258; called by muse, mutect2, varscan2
- NLRP11 | c.1862A>G p.Y621C | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV64088991; called by muse, mutect2, varscan2
- NLRP13 | c.2429G>A p.C810Y | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61624296; called by muse, mutect2, varscan2
- NLRP3 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV60231764, COSV60232893; called by muse, mutect2, varscan2
- NLRP4 | c.2209C>A p.P737T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV100017313; called by muse, mutect2, varscan2
- NLRP4 | c.2210C>A p.P737H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV100017318; called by muse, mutect2, varscan2
- NOVA1 | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV57488807, COSV99947691; called by muse, mutect2, varscan2
- NOX3 | c.1576C>G p.P526A | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50165476; called by muse, mutect2, varscan2
- NPR3 | c.702C>A p.Y234* | Nonsense Mutation (SNP) | VAF 56/264 reads (21%) | catalogued as COSV54093724; called by muse, mutect2, varscan2
- NRSN1 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65894698; called by muse, mutect2, varscan2
- NRXN1 | c.2804C>A p.T935K | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58497733; called by muse, mutect2, varscan2
- NRXN1 | c.1238T>C p.F413S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as COSV58497771; called by muse, mutect2, varscan2
- NTN4 | c.802G>C p.A268P | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59222636, COSV59224050; called by muse, mutect2, varscan2
- NTRK2 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.864); catalogued as rs1432834509, COSV52862359, COSV52884748; called by muse, mutect2, varscan2
- NTRK3 | c.1516A>G p.T506A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV58146414; called by muse, mutect2, varscan2
- NUGGC | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs751612628, COSV58435910, COSV58439665; called by muse, mutect2, varscan2
- NUP133 | c.2868G>T p.L956F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54575752; called by muse, mutect2, varscan2
- NXF3 | c.1160+1G>A p.X387_splice | Splice Site (SNP) | VAF 26/64 reads (41%) | catalogued as rs746686429, COSV67705336; called by muse, mutect2, varscan2
- OBSL1 | c.2971A>T p.I991L | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV54710867; called by muse, mutect2, varscan2
- OCA2 | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV100668808; called by muse, mutect2, varscan2
- OCA2 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV62340753; called by mutect2, varscan2
- OGDHL | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1380422404, COSV65104994; called by muse, mutect2, varscan2
- OR10A2 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as rs1308475870, COSV100225192; called by muse, mutect2, varscan2
- OR10G2 | c.295T>A p.F99I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV73390482; called by muse, mutect2, varscan2
- OR13G1 | c.870G>C p.Q290H | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV62945398; called by muse, mutect2, varscan2
- OR14K1 | c.429G>C p.M143I | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV99315529; called by muse, mutect2
- OR2B11 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV59511623, COSV59511767, COSV59511827; called by muse, mutect2, varscan2
- OR2G2 | c.314A>T p.Y105F | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.964); catalogued as COSV60742568; called by muse, mutect2, varscan2
- OR2G3 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.392); catalogued as COSV60683449; called by muse, mutect2, varscan2
- OR2L3 | c.699G>T p.R233S | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs766485201, COSV100741983, COSV63456497; called by muse, varscan2
- OR4A15 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.597); catalogued as COSV59038041; called by muse, mutect2
- OR4C15 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV58956134; called by muse, mutect2, varscan2
- OR4C46 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100060940, COSV60221458; called by muse, mutect2, varscan2
- OR4N2 | c.393C>A p.H131Q | Missense Mutation (SNP) | VAF 95/458 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV60053366; called by muse, mutect2, varscan2
- OR52K2 | c.46T>G p.L16V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57835917; called by muse, mutect2
- OR5B21 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV64482043, COSV64482315; called by muse, mutect2, varscan2
- OR5D18 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61738819; called by muse, mutect2, varscan2
- OR5K2 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV71143550; called by muse, mutect2, varscan2
- OR5T1 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV100479262; called by muse, mutect2, varscan2
- OR7G1 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53319158; called by muse, mutect2, varscan2
- OR8J3 | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV56884596; called by muse, mutect2, varscan2
- OR8S1 | c.889-1G>A p.X297_splice | Splice Site (SNP) | VAF 32/60 reads (53%) | catalogued as COSV59599772; called by muse, mutect2, varscan2
- OTOP3 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs773800453, COSV60915272; called by muse, mutect2, varscan2
- PAF1 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.057); catalogued as COSV55394752; called by muse, mutect2, varscan2
- PCDH15 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV57403387; called by muse, mutect2, varscan2
- PCDHGA3 | c.827A>C p.Q276P | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV54044033; called by muse, mutect2, varscan2
- PCMTD2 | c.778C>G p.H260D | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV55063060; called by muse, mutect2, varscan2
- PDGFRB | c.2200G>T p.G734W | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV55810670; called by muse, mutect2, varscan2
- PDK1 | c.944A>T p.K315M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99961529; called by muse, mutect2, varscan2
- PEG3 | c.1461C>G p.I487M | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV55627986, COSV55649421; called by muse, mutect2, varscan2
- PFAS | c.2702-1G>T p.X901_splice | Splice Site (SNP) | VAF 19/45 reads (42%) | catalogued as COSV58983737; called by muse, mutect2, varscan2
- PHF21A | c.628C>T p.P210S (on ENST00000418153 / NM_001101802.3; = p.P211S on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV57660609; called by muse, mutect2, varscan2
- PIBF1 | c.1418T>G p.L473R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV58328817; called by muse, mutect2, varscan2
- PLAA | c.544A>G p.R182G | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV68305704; called by muse, mutect2, varscan2
- POLG | c.2519T>C p.I840T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51525687; called by muse, mutect2, varscan2
- POLR2E | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV53125493; called by muse, mutect2, varscan2
- POM121L12 | c.767T>A p.L256Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen probably damaging (0.992); catalogued as COSV101374892, COSV68694587; called by muse, mutect2, varscan2
- PPP1R3A | c.2906C>A p.P969H | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV52894114; called by muse, mutect2, varscan2
- PPP1R3D | c.502T>G p.F168V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100674696; called by muse, mutect2, varscan2
- PPP2R5B | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV51213775; called by muse, mutect2, varscan2
- PROSER1 | c.2651C>A p.S884* | Nonsense Mutation (SNP) | VAF 64/160 reads (40%) | catalogued as COSV61489983; called by muse, mutect2, varscan2
- PRR16 | c.692T>C p.V231A (on ENST00000407149 / NM_001300783.2; = p.V208A on NM_016644.2) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.291); catalogued as COSV65406799; called by muse, mutect2, varscan2
- PRSS16 | c.1306G>C p.A436P | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV57917137; called by muse, mutect2
- PRSS55 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 101/338 reads (30%) | catalogued as COSV60809458; called by muse, mutect2, varscan2
- PRSS55 | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV60809464; called by muse, mutect2
- PRSS55 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100153900; called by muse, mutect2
- PRUNE2 | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV65048834; called by muse, mutect2
- PSMA6 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as COSV54839365; called by muse, mutect2, varscan2
- PTCRA | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58976880; called by muse, mutect2
- PTPRB | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as COSV57718354; called by muse, mutect2, varscan2
- PTPRO | c.527C>A p.T176K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs944279283, COSV55524142; called by muse, mutect2, varscan2
- PTPRT | c.3970C>T p.R1324W | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs956451753, COSV61975515; called by muse, mutect2, varscan2
- PTPRU | c.1143A>C p.A381= | Splice Region (SNP) | VAF 13/37 reads (35%) | catalogued as rs778243643, COSV60537503; called by muse, mutect2, varscan2
- PTPRZ1 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 28/123 reads (23%) | catalogued as COSV66446485; called by muse, mutect2, varscan2
- PUM1 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as COSV57091997; called by muse, mutect2
- PUS7 | c.1294_1295insT p.T432Ifs*40 | Frame Shift Ins (INS) | VAF 37/176 reads (21%) | catalogued as COSV100708672; called by mutect2, pindel, varscan2
- PXDN | c.2178C>A p.H726Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV53247268; called by muse, mutect2, varscan2
- PXK | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs144000489, COSV57095006; called by muse, mutect2, varscan2
- PYHIN1 | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV63724260; called by muse, mutect2, varscan2
- PYHIN1 | c.625A>T p.I209F | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV63724268; called by muse, mutect2, varscan2
- R3HDM1 | c.37A>T p.T13S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV51533617; called by muse, mutect2, varscan2
- RAD51AP2 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs868146529, COSV67589385; called by muse, mutect2, varscan2
- RALGAPA2 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV52512744; called by muse, mutect2, varscan2
- RALYL | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV72826150; called by muse, mutect2
- RANBP2 | c.4306A>G p.I1436V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs1558921187, COSV51709526; called by muse, mutect2, varscan2
- RB1 | c.610del p.X204_splice | Splice Site (DEL) | VAF 21/49 reads (43%) | catalogued as CS030549, COSV57315273; called by mutect2, pindel, varscan2
- RBM15 | c.812G>A p.S271N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV63924584; called by muse, mutect2
- RBM24 | c.214C>A p.P72T (on ENST00000379052 / NM_001143942.2; = p.P27T on NM_153020.2) | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV59005191; called by muse, mutect2, varscan2
- RBMXL2 | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as COSV60981946; called by muse, mutect2, varscan2
- RCOR1 | c.1184T>G p.V395G | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51772963; called by muse, mutect2, varscan2
- REG3A | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV59412234; called by muse, mutect2, varscan2
- RESF1 | c.4725G>C p.K1575N | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV57026211; called by muse, mutect2, varscan2
- RFX7 | c.816G>T p.P272= (on ENST00000559447 / NM_001368074.1; = p.P369= on NM_022841.7 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 9/40 reads (23%) | catalogued as COSV57969367; called by muse, mutect2, varscan2
- RGS1 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV66506016, COSV66506682; called by muse, mutect2, varscan2
- RIMBP2 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55473272, COSV55485497; called by muse, mutect2, varscan2
- RNF133 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV57388429; called by muse, mutect2, varscan2
- RNF212 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV101260381; called by muse, mutect2, varscan2
- RNF216 | c.2408C>G p.A803G (on ENST00000425013 / NM_207116.3; = p.A860G on NM_207111.4) | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs201457738, COSV101111402; called by muse, mutect2, varscan2
- RNLS | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV59300882; called by muse, mutect2, varscan2
- RNMT | c.541A>T p.S181C | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51092187; called by muse, mutect2, varscan2
- RP1 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55112273, COSV55113855; called by muse, mutect2, varscan2
- RXRG | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | catalogued as COSV100717926; called by muse, varscan2
- RXRG | c.648C>A p.S216R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV100717935; called by muse, mutect2, varscan2
- S1PR1 | c.312G>T p.L104F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV59514155; called by muse, mutect2, varscan2
- SC5D | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50614113; called by muse, mutect2, varscan2
- SCAF11 | c.62-1G>A p.X21_splice | Splice Site (SNP) | VAF 28/64 reads (44%) | catalogued as COSV56979519, COSV99874176; called by muse, mutect2, varscan2
- SCN1A | c.4285-1G>T p.X1429_splice (on ENST00000303395 / NM_001202435.3; = p.X1418_splice on NM_006920.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 41/107 reads (38%) | catalogued as CS1513875, COSV57690006; called by muse, mutect2, varscan2
- SEC24C | c.2086C>A p.L696I | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59541853; called by muse, mutect2
- SEMA6C | c.24G>C p.M8I | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59008241; called by muse, mutect2, varscan2
- SERPINA9 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV54078902; called by muse, mutect2, varscan2
- SFMBT2 | c.1477C>G p.P493A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV62817449; called by muse, mutect2, varscan2
- SLC12A7 | c.761A>T p.Y254F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV53763170; called by muse, mutect2
- SLC12A9 | c.9C>A p.S3R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs145131568; called by muse, mutect2, varscan2
- SLC25A3 | c.547A>T p.M183L (on ENST00000228318 / NM_005888.3; = p.M182L on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV51848280, COSV99499265; called by muse, mutect2, varscan2
- SLC35B4 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65985577; called by muse, mutect2, varscan2
- SLC35G3 | c.579T>A p.Y193* | Nonsense Mutation (SNP) | VAF 75/190 reads (39%) | catalogued as COSV99269338; called by muse, mutect2, varscan2
- SLC39A12 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as COSV66202865; called by muse, mutect2, varscan2
- SLC4A2 | c.2879A>G p.Q960R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52542533; called by muse, mutect2, varscan2
- SLC8A1 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758440605, COSV60498041; called by muse, mutect2, varscan2
- SLCO2A1 | c.724+1G>T p.X242_splice | Splice Site (SNP) | VAF 33/68 reads (49%) | catalogued as CS126919, COSV60490017; called by muse, mutect2, varscan2
- SLFN13 | c.2247A>G p.I749M | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV53195957; called by muse, mutect2, varscan2
- SLIT2 | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV56597698; called by muse, mutect2, varscan2
- SLIT3 | c.4029C>A p.C1343* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV60635112; called by muse, mutect2, varscan2
- SMAD3 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039137, COSV59283274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCHD1 | c.4084C>T p.L1362F | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV55255371, COSV55269718, COSV55269875; called by muse, mutect2, varscan2
- SNX13 | c.2582G>A p.R861K | Missense Mutation (SNP) | VAF 100/285 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV68068509; called by muse, mutect2, varscan2
- SNX14 | c.1926G>C p.K642N (on ENST00000314673 / NM_001350535.1; = p.K589N on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59016749; called by muse, mutect2, varscan2
- SNX19 | c.351G>C p.W117C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56289323; called by muse, mutect2, varscan2
- SORCS1 | c.550A>G p.N184D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV53909286; called by muse, mutect2, varscan2
- SOX11 | c.714G>C p.Q238H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs1256714607, COSV58988434; called by muse, mutect2, varscan2
- SPEG | c.8927G>C p.R2976P | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56680815; called by muse, mutect2, varscan2
- SRBD1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 74/274 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV55406190; called by muse, mutect2, varscan2
- SRMS | c.1454G>T p.R485I | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV53918710; called by muse, mutect2, varscan2
- STAG2 | c.1622G>A p.R541K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV54374018; called by muse, mutect2, varscan2
- STK35 | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.267); catalogued as COSV55693125; called by muse, mutect2, varscan2
- STOML3 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65512047; called by muse, mutect2, varscan2
- SUGP1 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV53238506; called by muse, mutect2, varscan2
- SVEP1 | c.1396T>A p.C466S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57049150; called by muse, mutect2, varscan2
- SYF2 | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV52574631; called by muse, mutect2, varscan2
- SYMPK | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs763771090, COSV55616214; called by muse, mutect2, varscan2
- SYNM | c.3965A>T p.Q1322L | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV50444887; called by muse, mutect2, varscan2
- SYNPO2 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV61118488; called by muse, mutect2, varscan2
- SZT2 | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs884257, COSV100987706; called by muse, mutect2, varscan2
- TAAR8 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 113/189 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV51587367; called by muse, mutect2, varscan2
- TAS2R60 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.216); catalogued as COSV60330526; called by muse, mutect2, varscan2
- TBX15 | c.1426C>A p.Q476K (on ENST00000369429 / NM_001330677.2; = p.Q370K on NM_152380.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV99254888; called by muse, mutect2, varscan2
- TBX20 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101282435; called by muse, mutect2, varscan2
- TCTEX1D1 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51075498, COSV51077255; called by muse, mutect2, varscan2
- TEC | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV63353989; called by muse, mutect2, varscan2
- TEX13B | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57204000; called by muse, mutect2, varscan2
- TFAP4 | c.770C>A p.S257* | Nonsense Mutation (SNP) | VAF 91/164 reads (55%) | catalogued as COSV52599214, COSV52599232; called by muse, mutect2, varscan2
- TGM2 | c.511T>C p.S171P | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV63932519; called by muse, mutect2
- THSD7A | c.4789C>T p.P1597S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV68472361; called by muse, mutect2, varscan2
- TIAM2 | c.204T>A p.F68L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated, low confidence (0.89); PolyPhen possibly damaging (0.626); catalogued as COSV59705133; called by muse, mutect2, varscan2
- TIGD7 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.808); catalogued as rs776667996, COSV99240031; called by muse, mutect2, varscan2
- TLR4 | c.871G>C p.A291P (on ENST00000355622 / NM_138554.5; = p.A251P on NM_003266.4) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as rs889353848, COSV62924412, COSV62924504; called by muse, mutect2, varscan2
- TMEM132A | c.2416G>T p.G806C (on ENST00000453848 / NM_178031.3; = p.G807C on NM_017870.4) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs772777798, COSV50025961; called by muse, mutect2, varscan2
- TMEM151A | c.122C>A p.S41* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as COSV59173277, COSV59175533; called by muse, mutect2, varscan2
- TMEM19 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57000289; called by muse, mutect2, varscan2
- TMEM270 | c.28A>T p.S10C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57639892; called by muse, mutect2, varscan2
- TMPRSS11A | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV58361476; called by muse, mutect2, varscan2
- TOM1L2 | c.1333G>T p.D445Y (on ENST00000379504 / NM_001350333.2; = p.D395Y on NM_001033551.3) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100541268; called by muse, mutect2, varscan2
- TREML4 | c.243C>A p.Y81* | Nonsense Mutation (SNP) | VAF 53/92 reads (58%) | catalogued as COSV58386590; called by muse, mutect2, varscan2
- TRIP12 | c.2822C>T p.T941I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as COSV52273631; called by muse, mutect2, varscan2
- TRMT10C | c.1068G>T p.M356I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV59306791, COSV59307091; called by muse, mutect2, varscan2
- TRPC4 | c.1947A>C p.E649D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as COSV58992958; called by muse, mutect2, varscan2
- TSC22D4 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV55725561; called by muse, mutect2
- TTC37 | c.3142C>T p.L1048F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs1184492224, COSV62457152; called by muse, mutect2, varscan2
- TTN | c.4928G>T p.C1643F (on ENST00000591111; = p.C1597F on NM_003319.4) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | PolyPhen probably damaging (0.997); catalogued as COSV60382778; called by muse, mutect2, varscan2
- UACA | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV59860579; called by muse, mutect2, varscan2
- UBE2Q2 | c.673+1G>A p.X225_splice | Splice Site (SNP) | VAF 71/186 reads (38%) | catalogued as COSV51197086; called by muse, mutect2, varscan2
- UBE2T | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV66153737; called by muse, mutect2, varscan2
- UBR4 | c.6205T>G p.Y2069D | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV64400792; called by muse, mutect2
- URI1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745532513, COSV56353484; called by muse, mutect2
- USH2A | c.1358C>A p.T453K | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56337122, COSV56446641; called by muse, mutect2, varscan2
- VCAM1 | c.1594A>T p.M532L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV54122593; called by muse, mutect2, varscan2
- VPS28 | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99465985; called by muse, mutect2, varscan2
- VRK2 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV60880994; called by muse, mutect2, varscan2
- VTA1 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312233054, COSV100859276; called by muse, mutect2, varscan2
- WDR62 | c.557G>T p.W186L | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV54340052; called by muse, mutect2, varscan2
- XCL2 | c.250A>C p.M84L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63194891; called by muse, mutect2
- XIRP2 | c.6643G>A p.G2215R (on ENST00000628543; = p.G2390R on NM_152381.6) | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.243); catalogued as COSV54737701; called by muse, mutect2, varscan2
- XKR9 | c.517T>A p.C173S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV101281981; called by muse, mutect2, varscan2
- ZBTB11 | c.3106G>T p.A1036S | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.026); catalogued as COSV57247206; called by muse, mutect2, varscan2
- ZCCHC12 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 79/146 reads (54%) | catalogued as COSV59573118; called by muse, mutect2, varscan2
- ZFHX4 | c.7524G>T p.W2508C | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51499202; called by muse, mutect2, varscan2
- ZFP3 | c.1499G>C p.C500S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV100603927; called by muse, mutect2
- ZFYVE26 | c.7372-2A>T p.X2458_splice | Splice Site (SNP) | VAF 8/62 reads (13%) | catalogued as COSV61334087; called by muse, mutect2, varscan2
- ZNF223 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV71571773; called by muse, mutect2, varscan2
- ZNF337 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV53323243; called by muse, mutect2, varscan2
- ZNF33A | c.2050A>G p.R684G (on ENST00000458705 / NM_006974.3; = p.R685G on NM_006954.2) | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56728125; called by muse, mutect2, varscan2
- ZNF362 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100987075; called by muse, mutect2, varscan2
- ZNF556 | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100298963; called by muse, mutect2, varscan2
- ZNF605 | c.1463A>T p.E488V | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV100053576; called by muse, mutect2, varscan2
- ZNF630 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs1556908434, COSV52098399; called by muse, mutect2, varscan2
- ZNF648 | c.1492C>A p.H498N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60572999; called by muse, mutect2
- ZNF667 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV52640001; called by muse, mutect2, varscan2
- ZNF777 | c.266A>T p.Q89L | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as COSV56100582; called by muse, mutect2, varscan2
- ZNF800 | c.1624C>T p.H542Y | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56180396; called by muse, mutect2, varscan2
- ZNF831 | c.4495G>T p.V1499L | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV64045787; called by muse, mutect2, varscan2
- ZSCAN1 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.114); catalogued as COSV56608899; called by muse, mutect2, varscan2
- ZSWIM5 | c.1750A>T p.K584* | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | catalogued as COSV62734189, COSV62737392; called by muse, mutect2, varscan2
- ZWILCH | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV57183624; called by muse, mutect2
- ADAMTSL1 | c.5097del p.N1700Tfs*41 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.3616del p.L1206Cfs*58 (on ENST00000506720 / NM_001322402.2; = p.L1138Cfs*58 on NM_015236.6) | Frame Shift Del (DEL) | VAF 25/93 reads (27%) | called by mutect2, pindel, varscan2
- ATP6V1B2 | c.705del p.V236* | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- CASS4 | c.2101del p.E701Rfs*47 | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | called by mutect2, varscan2
- GOLPH3L | c.250del p.A84Pfs*19 | Frame Shift Del (DEL) | VAF 66/146 reads (45%) | called by mutect2, pindel, varscan2
- GPR174 | c.261del p.P88Lfs*10 | Frame Shift Del (DEL) | VAF 17/32 reads (53%) | called by mutect2, pindel, varscan2
- GRAMD1B | c.1939del p.Y647Tfs*19 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- IGKV1D-42 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- IGLV3-32 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- MRC1 | c.3080G>T p.G1027V | Missense Mutation (SNP) | VAF 99/432 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MUC2 | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NCAM2 | c.1004_1016del p.K335Mfs*32 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel
- OR1L1 | c.984del p.V329Yfs*2 (on ENST00000373686; = p.V279Yfs*2 on NM_001005236.3) | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | called by mutect2, pindel, varscan2
- OR4C6 | c.587del p.L196* | Frame Shift Del (DEL) | VAF 30/137 reads (22%) | called by mutect2, pindel, varscan2
- OR8D2 | c.520del p.V174Sfs*12 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- PJVK | c.211+2dup p.X71_splice | Splice Site (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel
- PRAMEF14 | c.521G>T p.R174M | Missense Mutation (SNP) | VAF 152/666 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRAMEF18 | c.367T>A p.S123T | Missense Mutation (SNP) | VAF 92/473 reads (19%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.915); called by mutect2, varscan2
- PRAMEF2 | c.1156A>T p.S386C | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- PRDM7 | c.920del p.G307Efs*10 | Frame Shift Del (DEL) | VAF 49/179 reads (27%) | called by mutect2, pindel, varscan2
- RBP3 | c.947C>A p.A316D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- REG3A | c.80_93del p.E27Gfs*53 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | called by mutect2, pindel
- SLC26A4 | c.1414_1415del p.W472Efs*4 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | called by pindel, varscan2
- SPATA31A1 | c.2714G>T p.W905L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.33); called by mutect2, varscan2
- SPATA31A1 | c.3724C>A p.P1242T | Missense Mutation (SNP) | VAF 149/702 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.898); called by muse, varscan2
- TPTE | c.1405G>C p.G469R (on ENST00000618007 / NM_199261.4; = p.G451R on NM_199259.4) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZNF26 | c.1230G>T p.K410N | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF658 | c.1160G>C p.G387A | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- AC100868.1 | c.1887G>T p.G629= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV99227106; called by muse, mutect2, varscan2
- ACTA1 | c.1113C>A p.I371= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as COSV100796805; called by muse, mutect2, varscan2
- ADCY2 | c.807G>T p.A269= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV57903216; called by muse, varscan2
- AFF2 | c.1119T>A p.T373= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV54009481; called by muse, mutect2, varscan2
- AGT | c.111C>T p.Y37= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV64185588; called by muse, mutect2, varscan2
- ALK | c.1356G>C p.G452= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV66591705; called by muse, mutect2, varscan2
- ANGPT1 | c.663C>G p.G221= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV52446296, COSV52458589; called by muse, mutect2
- ANKRD26 | c.4332T>C p.C1444= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV65778793; called by muse, mutect2
- ANO10 | c.960A>T p.P320= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV52736825; called by muse, mutect2, varscan2
- APOL4 | c.717C>A p.A239= (on ENST00000352371 / NM_145660.2; = p.A236= on NM_030643.4) | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV60653991, COSV60655502; called by muse, mutect2
- ARHGAP36 | c.1041G>C p.L347= | Silent (SNP) | VAF 88/171 reads (51%) | catalogued as COSV52272726, COSV99357609; called by muse, mutect2, varscan2
- ASIC3 | c.1071C>A p.A357= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV52526207; called by muse, mutect2, varscan2
- ASTN2 | c.1266C>A p.R422= (on ENST00000313400 / NM_001365069.1; = p.R371= on NM_014010.5) | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV57821156; called by muse, mutect2, varscan2
- C11orf42 | c.313C>A p.R105= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV56409884, COSV56411333; called by muse, mutect2, varscan2
- CACNA2D4 | c.342C>A p.I114= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV54962205; called by muse, mutect2, varscan2
- CAD | c.870G>A p.L290= | Silent (SNP) | VAF 13/304 reads (4%) | catalogued as COSV53032498, COSV99255458; called by muse, mutect2
- CCDC40 | c.291T>C p.Y97= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV53904956; called by muse, mutect2
- CDH10 | c.2184C>T p.P728= | Silent (SNP) | VAF 15/247 reads (6%) | catalogued as rs760251937, COSV52571475, COSV52600084; called by muse, mutect2
- CDK6 | c.969G>A p.L323= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1018330652, COSV56013329; called by muse, mutect2, varscan2
- CEACAM5 | c.333C>T p.N111= | Silent (SNP) | VAF 27/347 reads (8%) | catalogued as rs1327684522, COSV55755669; called by muse, mutect2
- CEP89 | c.726A>T p.A242= | Silent (SNP) | VAF 9/203 reads (4%) | catalogued as COSV59868170; called by muse, mutect2
- CHRFAM7A | c.549C>G p.T183= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as COSV100241732; called by muse, mutect2, varscan2
- CHRNA4 | c.1839G>A p.G613= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs952941182, COSV64721306; called by muse, mutect2, varscan2
- CLDN9 | c.561G>A p.P187= | Silent (SNP) | VAF 52/98 reads (53%) | catalogued as rs773530388, COSV60911643; called by muse, mutect2, varscan2
- CLVS1 | c.63C>A p.A21= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100369867, COSV57983890; called by muse, mutect2, varscan2
- COL1A2 | c.1002T>C p.G334= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV51967006; called by muse, mutect2, varscan2
- COX7A2 | c.141G>T p.T47= | Silent (SNP) | VAF 107/217 reads (49%) | catalogued as COSV100034565; called by muse, mutect2, varscan2
- CPNE9 | c.1437G>T p.V479= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV56070104; called by muse, mutect2, varscan2
- CSMD2 | c.5412G>A p.R1804= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV53969024; called by muse, mutect2
- CTNND2 | c.93G>T p.L31= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as COSV58931998; called by muse, mutect2, varscan2
- CUBN | c.5703A>G p.E1901= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV64728518; called by muse, mutect2, varscan2
- CUL7 | c.2238G>A p.L746= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as COSV54822614; called by muse, mutect2, varscan2
- DAB1 | c.1113C>T p.P371= (on ENST00000371231; = p.P338= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs866883656, COSV64698834; called by muse, mutect2, varscan2
- DDHD2 | c.510G>C p.V170= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV68158942; called by muse, mutect2, varscan2
- DGKB | c.78A>T p.T26= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV51823091; called by mutect2, varscan2
- DOK2 | c.1140C>A p.G380= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV52390345; called by muse, mutect2, varscan2
- DOP1B | c.384G>A p.L128= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV54281927; called by muse, varscan2
- EME2 | c.528C>T p.A176= | Silent (SNP) | VAF 17/167 reads (10%) | catalogued as rs1016209981, COSV99169835; called by muse, mutect2
- EVC2 | c.2304G>T p.V768= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs139936564, COSV60403944; called by muse, mutect2, varscan2
- FAM78B | c.673C>A p.R225= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs1314055154, COSV57982911; called by muse, varscan2
- FFAR3 | c.57G>T p.S19= | Silent (SNP) | VAF 80/256 reads (31%) | catalogued as rs371169601, COSV100588322; called by muse, varscan2
- FLRT2 | c.1719C>A p.T573= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV58151187; called by muse, mutect2, varscan2
- FRMD5 | c.513G>A p.L171= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV68725869; called by muse, mutect2, varscan2
- FSCN3 | c.1174C>A p.R392= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs192546949, COSV56172120; called by muse, mutect2, varscan2
- GNAT2 | c.795C>A p.V265= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100655934; called by muse, mutect2, varscan2
- GPR158 | c.2169C>A p.A723= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV66280410; called by muse, mutect2, varscan2
- GRIN3A | c.600C>A p.P200= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV62458971; called by muse, mutect2, varscan2
- GRM3 | c.810C>G p.R270= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV64480463, COSV64480794; called by muse, mutect2, varscan2
- GZMK | c.252A>T p.A84= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV50249109; called by muse, mutect2, varscan2
- HIVEP2 | c.6438C>T p.P2146= | Silent (SNP) | VAF 54/94 reads (57%) | catalogued as COSV50074376; called by muse, varscan2
- HOXB9 | c.342G>C p.A114= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV60817896; called by muse, mutect2
- HTT | c.4363C>T p.L1455= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV61870393; called by muse, mutect2, varscan2
- INTS2 | c.132T>A p.L44= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV52157105; called by muse, mutect2, varscan2
- ITGB8 | c.945C>T p.V315= | Silent (SNP) | VAF 48/72 reads (67%) | catalogued as COSV56015073; called by muse, mutect2
- KLHL12 | c.537G>T p.V179= | Silent (SNP) | VAF 27/226 reads (12%) | catalogued as rs1160015614, COSV63042959; called by muse, mutect2, varscan2
- KRT38 | c.171G>T p.V57= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV55847803; called by muse, mutect2, varscan2
- KRTAP6-3 | c.183G>A p.L61= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV66963424; called by muse, mutect2, varscan2
- LCOR | c.3423A>G p.K1141= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV53718820; called by muse, mutect2, varscan2
- LRRC15 | c.651T>C p.F217= | Silent (SNP) | VAF 126/224 reads (56%) | catalogued as COSV61651929; called by muse, mutect2, varscan2
- LRRTM1 | c.966G>C p.V322= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54444831, COSV54447298; called by muse, mutect2, varscan2
- MADD | c.3804A>T p.A1268= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV60630162; called by muse, mutect2, varscan2
- MAL | c.141C>T p.P47= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV59432926; called by muse, mutect2, varscan2
- MBP | c.639G>T p.R213= (on ENST00000355994 / NM_001025101.2; = p.R106= on NM_002385.3) | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs770611471, COSV62830769; called by muse, mutect2, varscan2
- MKI67 | c.1245A>G p.P415= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV64077360; called by muse, mutect2, varscan2
- MKRN3 | c.1521G>T p.L507= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV58812499; called by muse, mutect2, varscan2
- MRAP | c.30A>T p.P10= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100353361; called by muse, mutect2, varscan2
- MRGPRX4 | c.186C>A p.S62= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV100049872, COSV58591257; called by muse, mutect2, varscan2
- MUC3A | c.8820C>A p.R2940= | Silent (SNP) | VAF 66/374 reads (18%) | catalogued as COSV60225481; called by muse, mutect2, varscan2
- MYH13 | c.2466C>T p.I822= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as COSV52844514; called by muse, mutect2, varscan2
- NCR1 | c.30C>T p.C10= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs371994983; called by muse, mutect2, varscan2
- NEB | c.11340C>A p.A3780= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs951171826, COSV99428621; called by muse, mutect2, varscan2
- NES | c.3681G>T p.P1227= | Silent (SNP) | VAF 88/188 reads (47%) | catalogued as COSV63960809, COSV63961748; called by muse, mutect2, varscan2
- NINL | c.177C>T p.A59= | Silent (SNP) | VAF 77/239 reads (32%) | catalogued as COSV54009688; called by muse, mutect2, varscan2
- NLRP3 | c.114C>A p.P38= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV60231642, COSV60231753; called by muse, mutect2, varscan2
- NPHS1 | c.2991C>T p.T997= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV62286392; called by muse, mutect2
- NUDCD1 | c.1650A>G p.L550= | Silent (SNP) | VAF 86/372 reads (23%) | catalogued as COSV53461125; called by muse, varscan2
- OR10G9 | c.633C>T p.L211= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV66686928; called by muse, mutect2, varscan2
- OR2B11 | c.771A>T p.L257= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as COSV59511757; called by muse, mutect2, varscan2
- OR4B1 | c.196T>C p.L66= | Silent (SNP) | VAF 71/198 reads (36%) | catalogued as COSV58884077; called by muse, mutect2, varscan2
- OR4D11 | c.681T>C p.S227= | Silent (SNP) | VAF 53/244 reads (22%) | catalogued as COSV57587340; called by muse, mutect2, varscan2
- OR4D9 | c.717C>A p.T239= | Silent (SNP) | VAF 114/285 reads (40%) | catalogued as COSV100260031; called by muse, mutect2, varscan2
- OR5M8 | c.834C>A p.T278= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV59118446; called by muse, mutect2, varscan2
- OR6K2 | c.927T>A p.A309= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV62744321; called by muse, mutect2, varscan2
- OR8J1 | c.114C>G p.T38= | Silent (SNP) | VAF 54/231 reads (23%) | catalogued as COSV57320313; called by muse, mutect2, varscan2
- OR9A4 | c.216C>T p.V72= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV71886153; called by muse, mutect2
- PABPC1 | c.1170A>T p.R390= | Silent (SNP) | VAF 25/217 reads (12%) | catalogued as COSV59408427; called by muse, mutect2, varscan2
- PAN2 | c.1107C>T p.S369= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV57756346; called by muse, mutect2, varscan2
- PAPPA | c.1323C>A p.R441= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV60292879; called by muse, mutect2, varscan2
- PBLD | c.180A>T p.A60= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV53267500; called by muse, mutect2, varscan2
- PCDH11X | c.3633A>G p.P1211= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV53509161; called by muse, mutect2, varscan2
- PCDH15 | c.5205C>A p.A1735= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100219976, COSV57403348; called by muse, mutect2
- PCDH15 | c.1371T>A p.T457= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV57403365; called by muse, mutect2, varscan2
- PCDH17 | c.555C>T p.S185= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs772918389, COSV64980049; called by muse, mutect2, varscan2
- PCDHB4 | c.2262G>A p.L754= | Silent (SNP) | VAF 71/158 reads (45%) | catalogued as rs782253966, COSV52027564; called by muse, mutect2, varscan2
- PCDHGA1 | c.2109C>G p.V703= | Silent (SNP) | VAF 76/140 reads (54%) | catalogued as COSV65300179; called by muse, mutect2, varscan2
- PELI2 | c.405C>T p.T135= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV50717050, COSV99954044; called by muse, mutect2, varscan2
- PENK | c.741C>A p.G247= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as COSV59241385, COSV59242711; called by muse, mutect2, varscan2
- PIK3CG | c.27C>A p.P9= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs772306261, COSV63253761; called by muse, mutect2, varscan2
- PKD1L1 | c.5376G>A p.L1792= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV56960666, COSV56979728; called by muse, mutect2, varscan2
- PLCB4 | c.795C>T p.A265= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV53820301; called by muse, mutect2, varscan2
- PLCXD3 | c.264A>G p.L88= | Silent (SNP) | VAF 15/158 reads (9%) | catalogued as COSV60619445; called by muse, mutect2
- PLIN4 | c.144G>A p.Q48= (on ENST00000301286; = p.Q63= on NM_001367868.2) | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV56699621; called by muse, mutect2, varscan2
- PNPLA8 | c.894A>T p.V298= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV57555120; called by muse, mutect2, varscan2
- PRLR | c.1470G>C p.T490= | Silent (SNP) | VAF 83/268 reads (31%) | catalogued as COSV51499272, COSV51501185; called by muse, mutect2, varscan2
- PTPN14 | c.1575A>T p.P525= | Silent (SNP) | VAF 59/266 reads (22%) | catalogued as COSV65289193; called by muse, mutect2, varscan2
- PXDN | c.3489G>C p.R1163= | Silent (SNP) | VAF 40/185 reads (22%) | catalogued as COSV53247259; called by muse, mutect2, varscan2
- RASSF2 | c.183C>A p.G61= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV65083408; called by muse, mutect2, varscan2
- RFX5 | c.1746G>A p.K582= | Silent (SNP) | VAF 33/222 reads (15%) | catalogued as COSV51841914; called by muse, mutect2, varscan2
- RGS12 | c.4212G>C p.A1404= (on ENST00000336727; = p.A756= on NM_198227.2) | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100122848, COSV58757882; called by muse, mutect2, varscan2
- RNF213 | c.14304C>G p.L4768= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as COSV60410139; called by muse, mutect2, varscan2
- RNF216 | c.2409G>C p.A803= (on ENST00000425013 / NM_207116.3; = p.A860= on NM_207111.4) | Silent (SNP) | VAF 48/214 reads (22%) | catalogued as COSV101111401; called by muse, mutect2, varscan2
- RNF216 | c.1770C>T p.A590= (on ENST00000425013 / NM_207116.3; = p.A647= on NM_207111.4) | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs200434435, COSV66289005; called by muse, mutect2, varscan2
- ROBO3 | c.2337G>A p.L779= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV67303225; called by muse, mutect2, varscan2
- RP1L1 | c.5151C>T p.P1717= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as COSV66760947; called by muse, mutect2, varscan2
- RXFP1 | c.174T>C p.D58= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV57057456; called by muse, mutect2, varscan2
- SCN9A | c.5463C>G p.V1821= (on ENST00000303354; = p.V1810= on NM_002977.3) | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as COSV57626720; called by muse, mutect2, varscan2
- SIGLEC10 | c.1488C>A p.P496= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs769982252, COSV59487155; called by muse, mutect2, varscan2
- SIGLEC8 | c.903C>A p.T301= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV58476098; called by muse, mutect2, varscan2
- SLC12A3 | c.624C>T p.S208= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV52639618; called by muse, mutect2
- SLC35F2 | c.696G>T p.V232= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs750265998, COSV56185848; called by muse, mutect2, varscan2
- SLC9A2 | c.1125C>T p.F375= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV52129344; called by muse, mutect2
- SLC9A9 | c.1029C>A p.V343= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as rs923977114, COSV57247207; called by muse, mutect2, varscan2
- SMCHD1 | c.4203C>T p.I1401= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV55269905; called by muse, mutect2, varscan2
- SNX8 | c.735G>T p.R245= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV56130583; called by muse, mutect2, varscan2
- SP110 | c.936C>G p.L312= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV51277091; called by muse, mutect2
- STAG1 | c.2865G>A p.L955= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV52625171; called by muse, mutect2, varscan2
- STIL | c.1743A>T p.S581= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV54554239; called by muse, mutect2, varscan2
- TBX15 | c.1425C>A p.S475= (on ENST00000369429 / NM_001330677.2; = p.S369= on NM_152380.3) | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs764932680, COSV99254892; called by muse, mutect2, varscan2
- TCERG1L | c.561G>T p.G187= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV64048382, COSV64058666; called by muse, mutect2, varscan2
- TENM3 | c.1998G>T p.T666= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV69320915; called by muse, mutect2, varscan2
- TIA1 | c.411G>T p.V137= (on ENST00000433529 / NM_001351511.1; = p.V126= on NM_022037.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV57008694; called by muse, mutect2, varscan2
- TLE4 | c.2286G>T p.G762= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV54642326; called by muse, mutect2, varscan2
- TNN | c.3556C>A p.R1186= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV53436968; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1230G>A p.V410= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV50562151; called by muse, mutect2, varscan2
- TRAPPC9 | c.1374G>T p.A458= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV66910492; called by muse, mutect2, varscan2
- TRIM21 | c.1338C>T p.F446= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV54346450; called by muse, mutect2, varscan2
- TSHZ2 | c.2091C>A p.A697= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as COSV61592005; called by muse, mutect2
- TTN | c.102810C>G p.G34270= (on ENST00000591111; = p.G26846= on NM_003319.4) | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV60382723; called by muse, mutect2
- UBASH3A | c.1440C>T p.A480= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV52316575; called by muse, mutect2, varscan2
- UNC13B | c.840T>C p.Y280= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as COSV65939071; called by muse, mutect2
- VWCE | c.2466T>C p.G822= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV57115826; called by muse, mutect2, varscan2
- ZNF560 | c.411T>C p.D137= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs755674240, COSV56872144; called by muse, mutect2, varscan2
- ZNF80 | c.768C>T p.Y256= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV57362776; called by muse, mutect2, varscan2
- ZNF831 | c.2415C>A p.V805= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as COSV64045781; called by muse, mutect2, varscan2
- AC073310.1 | n.385_387delinsTT | RNA (DEL) | VAF 47/211 reads (22%) | called by pindel, varscan2*
- AL132655.6 | chr20:58840836 C>G | 5'Flank (SNP) | VAF 5/48 reads (10%) | catalogued as rs1316920070, COSV100005834, COSV100007453, COSV100007872; called by muse, mutect2
- AP000769.5 | chr11:65500223 A>G | 5'Flank (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- BIRC8 | n.1053A>G | RNA (SNP) | VAF 29/73 reads (40%) | catalogued as rs1204553378, COSV70348075; called by muse, mutect2, varscan2
- DST | c.4297-1199A>T | Intron (SNP) | VAF 27/102 reads (26%) | catalogued as COSV99760566; called by muse, mutect2, varscan2
- GABRA3 | c.-26-27651G>T | Intron (SNP) | VAF 17/51 reads (33%) | catalogued as COSV64798190, COSV64806029; called by muse, mutect2, varscan2
- HTR3E | c.68-90G>T | Intron (SNP) | VAF 41/208 reads (20%) | catalogued as rs751429162, COSV100094540; called by muse, mutect2, varscan2
- KNOP1P1 | n.429C>A | RNA (SNP) | VAF 25/169 reads (15%) | called by muse, mutect2, varscan2
- MATK | c.-3del | 5'UTR (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- MIR365A | n.30G>T | RNA (SNP) | VAF 41/79 reads (52%) | called by muse, mutect2, varscan2
- MIR543 | n.25T>A | RNA (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- OR4F6 | c.-2C>G | 5'UTR (SNP) | VAF 44/153 reads (29%) | catalogued as COSV100187015; called by muse, mutect2, varscan2
- OR9A2 | c.*1C>A | 3'UTR (SNP) | VAF 58/121 reads (48%) | catalogued as COSV100628296; called by muse, mutect2, varscan2
- PPM1A | chr14:60245946 G>A | 5'Flank (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100349523; called by muse, varscan2
- TMEM196 | c.*27C>A | 3'UTR (SNP) | VAF 18/170 reads (11%) | catalogued as COSV68256711; called by muse, mutect2
- TOR1AIP2 | c.-147+12093dup | Intron (INS) | VAF 22/112 reads (20%) | called by mutect2, pindel, varscan2
- ZNF415 | c.-194-66G>C | Intron (SNP) | VAF 89/225 reads (40%) | catalogued as rs1380293769, COSV99702116; called by muse, mutect2, varscan2
